Surgical pathology report (de-identified scan), TCGA case TCGA-49-AAR0, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-AAR0-01A (Primary Tumor).

[page 1 of 4]
=====

INTERPRETATION AND DIAGNOSIS:

1. LUNG, RIGHT UPPER LOBE (LOBECTOMY): INFILTRATING MODERATELY DIFFERENTIATED ADENOCARCINOMA (1.7 CM). THE TUMOR DOES NOT INVADE THE PLEURA. BRONCHIAL AND VASCULAR MARGINS, NEGATIVE FOR TUMOR. TWO (2) HILAR LYMPH NODES, NEGATIVE FOR TUMOR. TWO (2) HYALINIZED PLEURAL PLAQUES IN THE NON-NEOPLASTIC LUNG. SEE NOTE.

2. LYMPH NODE, R4 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

3. LYMPH NODE, R7 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

NOTE: The pathologic stage is T1NoMx. This case was shown at the

*Electronic signature

=====

Clinical History:
LUNG MASS

GROSS DESCRIPTION

(Continued on next page.)

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: R Lung, upper lobe C84.1

5/20/14

[page 2 of 4]
PART #1: FS: RIGHT UPPER LOBE
Resident Pathologist:

FS: RIGHT UPPER LOBE: INFILTRATING POORLY DIFFERENTIATED CARCINOMA,
FAVOR NON-SMALL CELL.

Attending:
Pa:

The specimen is received fresh labeled [REDACTED] and designated right upper lobe. It consists of a grossly recognizable lobectomy specimen weighing 180 gms, and measuring 17.7 x 9 x 2.4 cm. There is a firm nodule palpable in the medial portion of the lower lobe. The pleura superficial to the area is inked black. On cut section, there is a firm tan gray nodule measuring 1.5 x 1.3 x 1.7 cm. The tumor approaches the inked pleural margin. The nodule measures 3.2 cm from the hilar structures, and 6.5 cm from the stapled margin. A portion of this nodule is submitted for frozen section diagnosis. There is a row of staples in the superior portion of the lung at the hilum. This row of staples measures 3.5 cm in length. The staples are removed, and the underlying pulmonary parenchyma is inked blue. There is a white circular nodule on the lateral pleural surface measuring 0.4 cm in maximum dimension. This nodule is located 6 cm from the apex and approximately 4 cm from the hilar structures. On cut section, the nodule is firm and gray-white in color. There is a second nodule on the lateral pleural surface approximately 4 cm from the inferior portion of the specimen. This nodule measures 0.7 cm in maximum dimension. It measures approximately 7 cm from the hilar structures. On cut section, the remainder of the non-neoplastic lung is tan red brown and spongy with focal anthracotic pigmentation. No other lesions are identified. A portion of the tumor is harvested for tissue banking purposes. Representative sections of the tumor and non-neoplastic lung are submitted.

SUMMARY OF SECTION:

1	- FSC	-1	(TUMOR)
1	- A	- M	(VASCULAR AND BRONCHIAL MARGINS)
1	- B	- 2	(HILAR LYMPH NODE)
1	- C	- 2	(HILAR LYMPH NODES)
3	-D-F	- 1	EA. (TUMOR)

(Continued on next page.)

[page 3 of 4]
=====

1	-G	- 2	(SUPERIOR PLEURAL NODULE)
1	-H	- 1	(INFERIOR PLEURAL NODULE)
3	- I-K	- 1	EA. (REPRESENTATIVE NON-NEOPLASTIC LUNG)
12	- TOTAL	- M	

PART #2: R-4
Resident Pathologist:

The specimen is received in formalin labeled [REDACTED] and designated R-4 lymph node. It consists of one piece of tan pink fibroadipose tissue measuring 1.2 x 0.5 x 0.5 cm. On cut section, the specimen is consistent with an anthracotic lymph node. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS:

1	A	- 2
1	- TOTAL	- 2

PART #3: R-7
Resident Pathologist:

The specimen is received in formalin labeled [REDACTED] and designated R-7 lymph node. It consists of one piece of tan pink tissue with anthracotic pigmentation measuring 1 x 0.5 x 0.5 cm. On cut section, the specimen is consistent with an anthracotic lymph node. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS:

1	- A	- 2
1	- TOTAL	- 2

[REDACTED]

=====

(End of Report)

printed

[page 4 of 4]
[REDACTED]

[REDACTED]

=====

INTERPRETATION AND DIAGNOSIS:

- 1) #1 (PROSTATE BX,)
- 2) MINUTE FOCUS OF ADENOCARCINOMA OF THE PROSTATE, GLEASON GRADE 3+3=6. SEE NOTE.

NOTE: The diagnosis of carcinoma is supported by the failure of immunoperoxidase staining for high molecular weight cytokeratin to demonstrate basal cells in the atypical glands.

*Signed copy on file

=====

GROSS DESCRIPTION

PART #1: PROSTATE
Resident Pathologist:

Received 4 slides

[REDACTED]

=====

(End of Report)

printed

Source: NCI Genomic Data Commons file ea95c034-7d94-4615-bcd4-c22c613c8a26 (TCGA-49-AAR0.FCCE5D5B-6AB6-441F-9FBF-65B23060C95B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).